Somatic mutation profile of tumor specimen 0DJILR from CCDI case PBBWZM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Liver; Age at diagnosis: 4.6 years (1,662 days).
Specimen 0DJILR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f1a5127-bd07-465d-8772-0bed2b843680.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJIKU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67155448-7964-4b0b-a34f-5ecf19a2dff2

The open-access MAF lists 26 somatic variants for this specimen: 10 protein-altering or splice-affecting, 7 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 7, 5'UTR 4, 3'UTR 2, 5'Flank 2, Nonsense Mutation 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>C p.Y220S | Missense Mutation (SNP) | VAF 350/385 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYO9B | c.6184A>G p.T2062A | Missense Mutation (SNP) | VAF 78/528 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.253); catalogued as rs780065513; called by mutect2, varscan2
- PTCHD4 | c.1820G>A p.R607H | Missense Mutation (SNP) | VAF 395/1972 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59781487; called by muse, mutect2, varscan2
- ARHGAP6 | c.710A>G p.Q237R | Missense Mutation (SNP) | VAF 33/872 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.026); called by muse, mutect2
- FIGNL2 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 159/294 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FLNA | c.4599C>G p.S1533R | Missense Mutation (SNP) | VAF 33/770 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, mutect2
- OBSL1 | c.5587del p.H1863Tfs*31 | Frame Shift Del (DEL) | VAF 231/875 reads (26%) | called by mutect2, pindel, varscan2
- SVEP1 | c.3283A>G p.T1095A | Missense Mutation (SNP) | VAF 804/1805 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- TTN | c.71296G>T p.G23766* (on ENST00000591111; = p.G16342* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 1895/2562 reads (74%) | called by mutect2, varscan2
- USP24 | c.1556G>A p.S519N | Missense Mutation (SNP) | VAF 36/1225 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); called by muse, mutect2
- AC068580.4 | c.1449C>T p.Y483= | Silent (SNP) | VAF 105/1501 reads (7%) | called by muse, mutect2
- CCDC27 | c.651C>G p.V217= | Silent (SNP) | VAF 415/1091 reads (38%) | called by muse, mutect2, varscan2
- COQ8A | c.267C>A p.A89= | Silent (SNP) | VAF 502/1091 reads (46%) | called by muse, mutect2, varscan2
- HEPHL1 | c.1047C>T p.V349= | Silent (SNP) | VAF 525/1317 reads (40%) | called by muse, mutect2, varscan2
- PI4KA | c.5949G>A p.S1983= | Silent (SNP) | VAF 208/736 reads (28%) | catalogued as rs751802146; called by muse, mutect2, varscan2
- RAD23B | c.357C>T p.P119= | Silent (SNP) | VAF 495/1071 reads (46%) | called by muse, mutect2, varscan2
- SUGP1 | c.819C>T p.F273= | Silent (SNP) | VAF 223/1217 reads (18%) | catalogued as rs931912650; called by muse, mutect2, varscan2
- AC109583.1 | c.-18G>A | 5'UTR (SNP) | VAF 251/615 reads (41%) | called by muse, mutect2, varscan2
- ADCY3 | c.*29C>G | 3'UTR (SNP) | VAF 234/1180 reads (20%) | catalogued as COSV53173980; called by mutect2, varscan2
- B3GAT2 | c.*3808C>G | 3'UTR (SNP) | VAF 18/385 reads (5%) | called by muse, mutect2
- CALM3 | chr19:46600882 C>A | 5'Flank (SNP) | VAF 226/598 reads (38%) | called by muse, mutect2, varscan2
- CBWD5 | c.708-75G>C | Intron (SNP) | VAF 45/149 reads (30%) | called by mutect2, varscan2
- NETO2 | c.-88G>C | 5'UTR (SNP) | VAF 42/51 reads (82%) | called by muse, mutect2, varscan2
- OR5AU1 | c.-148A>C | 5'UTR (SNP) | VAF 226/609 reads (37%) | called by muse, mutect2, varscan2
- PARL | chr3:183884908 G>T | 5'Flank (SNP) | VAF 94/167 reads (56%) | called by muse, mutect2, varscan2
- SLC17A6 | c.-75C>T | 5'UTR (SNP) | VAF 165/218 reads (76%) | catalogued as rs1437805858; called by muse, mutect2, varscan2
